Somatic mutation profile of tumor specimen ALCH-B1OB-TTR1-A (aliquot ALCH-B1OB-TTR1-A-1-0-D-A85H-36) from ALCHEMIST case ALCH-B1OB, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.0 years (25,941 days).
Specimen ALCH-B1OB-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7faca138-2515-4805-9979-e758abf7c1c8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1OB-NB1-A (Blood Derived Normal), aliquot ALCH-B1OB-NB1-A-1-0-D-A76C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/36307b32-7e59-4bcf-9b16-78089ced9748

The open-access MAF lists 176 somatic variants for this specimen: 109 protein-altering or splice-affecting, 33 silent, 34 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, Silent 33, Intron 15, Frame Shift Del 9, Splice Site 8, 5'UTR 8, Nonsense Mutation 7, 3'UTR 4, 5'Flank 3, In Frame Del 3, Splice Region 3, RNA 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STK11 | c.109C>T p.Q37* | Nonsense Mutation (SNP) | VAF 112/219 reads (51%) | catalogued as rs121913324, CD132642, CM044071, COSV58819862; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.375G>T p.T125= | Splice Region (SNP) | VAF 44/86 reads (51%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: not provided / likely pathogenic; called by mutect2, varscan2
- ANKRD17 | c.5422C>T p.R1808C | Missense Mutation (SNP) | VAF 101/291 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.764); catalogued as COSV58217044; called by muse, mutect2, varscan2
- ARMC3 | c.167-1G>T p.X56_splice | Splice Site (SNP) | VAF 42/102 reads (41%) | catalogued as COSV99959067; called by muse, mutect2, varscan2
- CARD9 | c.1435-1G>A p.X479_splice | Splice Site (SNP) | VAF 23/64 reads (36%) | catalogued as rs1353243639; called by muse, mutect2, varscan2
- CCDC178 | c.523A>G p.K175E | Missense Mutation (SNP) | VAF 91/329 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV100285080; called by muse, mutect2, varscan2
- CD55 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 97/565 reads (17%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs1367527886; called by muse, mutect2, varscan2
- COL6A1 | c.344G>C p.S115T | Missense Mutation (SNP) | VAF 133/349 reads (38%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.457); catalogued as rs372627181, COSV62614659; called by muse, mutect2, varscan2
- ERICH3 | c.2278C>A p.Q760K | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100445191; called by muse, mutect2, varscan2
- GRID2 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 44/159 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs779054312, COSV56289101; called by muse, mutect2, varscan2
- ITPRID1 | c.1533G>T p.M511I | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV60078670; called by muse, mutect2, varscan2
- JUN | c.809G>T p.R270L | Missense Mutation (SNP) | VAF 161/494 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64664673; called by muse, mutect2, varscan2
- KEAP1 | c.719G>T p.R240L | Missense Mutation (SNP) | VAF 54/86 reads (63%) | SIFT tolerated (0.51); PolyPhen benign (0.048); catalogued as COSV99408145; called by muse, mutect2, varscan2
- KLHL25 | c.1375G>T p.V459L | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1206016054; called by muse, mutect2
- MYLK3 | c.1361G>T p.G454V | Missense Mutation (SNP) | VAF 50/95 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.109); catalogued as COSV67363341; called by muse, mutect2, varscan2
- NBEAL1 | c.3923A>T p.D1308V | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.04); catalogued as rs900423516; called by muse, mutect2, varscan2
- NLRP3 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 100/381 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.255); catalogued as rs769647268, CM1414461, COSV60220167; called by muse, mutect2, varscan2
- NUCB2 | c.835G>T p.D279Y | Missense Mutation (SNP) | VAF 34/52 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV100083058; called by muse, mutect2, varscan2
- OR5D16 | c.489C>A p.C163* | Nonsense Mutation (SNP) | VAF 32/151 reads (21%) | catalogued as COSV65722193; called by muse, mutect2, varscan2
- OSBPL8 | c.2044G>T p.E682* | Nonsense Mutation (SNP) | VAF 36/80 reads (45%) | catalogued as COSV99674632; called by muse, mutect2, varscan2
- PSMB10 | c.160G>A p.G54S | Missense Mutation (SNP) | VAF 47/154 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1285142445; called by muse, mutect2, varscan2
- PTPN3 | c.1190A>G p.D397G | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.69); PolyPhen benign (0.017); catalogued as rs1469346763; called by muse, mutect2, varscan2
- REST | c.352G>T p.V118F | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as COSV58359965; called by muse, mutect2, varscan2
- RFX5 | c.608C>G p.A203G | Missense Mutation (SNP) | VAF 46/245 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100923834; called by muse, mutect2, varscan2
- RYR2 | c.796G>T p.A266S | Missense Mutation (SNP) | VAF 145/451 reads (32%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.736); catalogued as rs373326624, COSV63684169, COSV63713339; called by muse, mutect2, varscan2
- SLITRK4 | c.53C>A p.A18E | Missense Mutation (SNP) | VAF 21/24 reads (88%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as rs906371486; called by muse, mutect2, varscan2
- TAS2R7 | c.246G>A p.M82I | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT tolerated (0.39); PolyPhen benign (0.03); catalogued as rs369634234; called by muse, mutect2, varscan2
- THSD7B | c.439C>T p.Q147* | Nonsense Mutation (SNP) | VAF 86/144 reads (60%) | catalogued as COSV99754199; called by muse, mutect2, varscan2
- TMEM132A | c.1438C>T p.R480C (on ENST00000453848 / NM_178031.3; = p.R481C on NM_017870.4) | Missense Mutation (SNP) | VAF 53/159 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs151003082; called by muse, mutect2, varscan2
- TMEM9 | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 61/271 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.338); catalogued as rs777562215, COSV100947431; called by muse, mutect2, varscan2
- TTC14 | c.223C>G p.L75V | Missense Mutation (SNP) | VAF 56/365 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs1020598792; called by muse, mutect2, varscan2
- TYK2 | c.3308G>A p.S1103N | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.639); catalogued as rs757843261; called by muse, varscan2
- UTP25 | c.2213C>T p.A738V | Missense Mutation (SNP) | VAF 41/194 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); catalogued as rs760271966, COSV72227450, COSV72227480; called by muse, mutect2, varscan2
- ZNF688 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs1041737232; called by muse, mutect2, varscan2
- ACACB | c.972del p.N325Ifs*10 | Frame Shift Del (DEL) | VAF 54/174 reads (31%) | called by pindel, varscan2
- ADGRB3 | c.1856C>T p.S619F | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- AIPL1 | c.20T>A p.L7Q | Missense Mutation (SNP) | VAF 129/224 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANKRD26 | c.1243G>C p.D415H | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- ANKRD30B | c.3060_3067del p.E1021Kfs*11 | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | called by mutect2, pindel
- ARHGAP32 | c.452C>G p.S151C | Missense Mutation (SNP) | VAF 84/152 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- ATP1B4 | c.233C>T p.T78I | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2
- BMPR2 | c.589T>C p.S197P | Missense Mutation (SNP) | VAF 100/371 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- C9orf72 | c.1316T>G p.L439* | Nonsense Mutation (SNP) | VAF 82/187 reads (44%) | called by muse, mutect2, varscan2
- CACNG4 | c.832A>T p.T278S | Missense Mutation (SNP) | VAF 54/187 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CCDC15 | c.2407G>A p.E803K | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CFAP54 | c.3666C>G p.D1222E | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT tolerated (0.83); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- CHD9 | c.2986A>T p.I996F | Missense Mutation (SNP) | VAF 85/144 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- COL1A2 | c.3086A>C p.Q1029P | Missense Mutation (SNP) | VAF 126/358 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- CTBP1 | c.186C>G p.I62M | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- DCLRE1C | c.974T>C p.I325T (on ENST00000378278 / NM_001350965.2; = p.I210T on NM_022487.4) | Missense Mutation (SNP) | VAF 108/323 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- DGCR2 | c.1202_1216del p.Y401_G405del | In Frame Del (DEL) | VAF 46/187 reads (25%) | called by mutect2, pindel, varscan2
- DOCK10 | c.5555T>C p.L1852P | Missense Mutation (SNP) | VAF 83/225 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- DTL | c.1594A>G p.I532V | Missense Mutation (SNP) | VAF 203/333 reads (61%) | SIFT tolerated (0.5); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EPB41L2 | c.2399T>C p.V800A | Missense Mutation (SNP) | VAF 41/59 reads (69%) | SIFT tolerated (0.38); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EPS8L1 | c.1825_1837del p.L609Afs*47 (on ENST00000201647 / NM_133180.3; = p.L482Afs*47 on NM_017729.3) | Frame Shift Del (DEL) | VAF 72/118 reads (61%) | called by pindel, varscan2
- ERICH5 | c.604G>C p.E202Q | Missense Mutation (SNP) | VAF 122/241 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- FAM110B | c.328G>T p.G110C | Missense Mutation (SNP) | VAF 62/177 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- FUT6 | c.10C>G p.L4V | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- GDF10 | c.1301T>A p.I434N | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- GGN | c.310C>G p.L104V | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- GPR182 | c.110dup p.N37Kfs*6 | Frame Shift Ins (INS) | VAF 77/269 reads (29%) | called by mutect2, pindel, varscan2
- HERC1 | c.13763T>A p.V4588D | Missense Mutation (SNP) | VAF 96/298 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HGF | c.1705del p.Q569Sfs*13 | Frame Shift Del (DEL) | VAF 92/314 reads (29%) | called by mutect2, pindel, varscan2
- INTS4 | c.2714-1G>C p.X905_splice | Splice Site (SNP) | VAF 26/77 reads (34%) | called by muse, mutect2, varscan2
- IPO11 | c.278G>T p.G93V | Missense Mutation (SNP) | VAF 31/315 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2
- ITPRID2 | c.258-2A>G p.X86_splice | Splice Site (SNP) | VAF 84/173 reads (49%) | called by muse, mutect2, varscan2
- KCNH8 | c.2668A>C p.N890H | Missense Mutation (SNP) | VAF 53/133 reads (40%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNQ2 | c.2309_2335del p.D770_E778del (on ENST00000359125 / NM_172107.4; = p.D742_E750del on NM_004518.6) | In Frame Del (DEL) | VAF 19/78 reads (24%) | called by mutect2, pindel
- KDM5B | c.40_66del p.A14_P22del | In Frame Del (DEL) | VAF 44/214 reads (21%) | called by mutect2, pindel
- KIF1B | c.2845A>G p.T949A (on ENST00000377086 / NM_001365952.1; = p.T903A on NM_015074.3) | Missense Mutation (SNP) | VAF 71/193 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- LCK | c.1139T>C p.I380T | Missense Mutation (SNP) | VAF 9/206 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.609); called by muse, mutect2
- MAPK8IP1 | c.528_529del p.L177Efs*2 | Frame Shift Del (DEL) | VAF 124/528 reads (23%) | called by pindel, varscan2
- MBD1 | c.806G>T p.R269L | Missense Mutation (SNP) | VAF 69/320 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- MOCOS | c.2641G>A p.E881K | Missense Mutation (SNP) | VAF 66/321 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYO6 | c.1224-2A>G p.X408_splice | Splice Site (SNP) | VAF 60/102 reads (59%) | called by muse, mutect2, varscan2
- NEK8 | c.1131G>T p.Q377H | Missense Mutation (SNP) | VAF 82/214 reads (38%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- NFAT5 | c.3510_3514del p.Q1171Nfs*5 | Frame Shift Del (DEL) | VAF 42/200 reads (21%) | called by mutect2, pindel, varscan2
- OSGEP | c.35A>T p.N12I | Missense Mutation (SNP) | VAF 62/162 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OTOF | c.427G>C p.E143Q | Missense Mutation (SNP) | VAF 104/267 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- OTUD5 | c.755T>C p.M252T | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.37); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- P2RX4 | c.428-2A>C p.X143_splice | Splice Site (SNP) | VAF 50/119 reads (42%) | called by muse, mutect2, varscan2
- PAQR9 | c.1069G>T p.V357L | Missense Mutation (SNP) | VAF 60/286 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PCNT | c.2020G>C p.E674Q | Missense Mutation (SNP) | VAF 13/337 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- PPP1R15B | c.1437C>A p.N479K | Missense Mutation (SNP) | VAF 27/261 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- PTPN1 | c.1164del p.E391Sfs*13 | Frame Shift Del (DEL) | VAF 27/100 reads (27%) | called by mutect2, pindel, varscan2
- RAN | c.36+5G>A | Splice Region (SNP) | VAF 6/49 reads (12%) | called by muse, mutect2, varscan2
- RBM43 | c.682C>G p.L228V | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- ROBO1 | c.3757G>T p.V1253L | Missense Mutation (SNP) | VAF 67/208 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- RPRD2 | c.3111dup p.G1038Wfs*16 | Frame Shift Ins (INS) | VAF 57/312 reads (18%) | called by mutect2, pindel, varscan2
- RRN3 | c.615G>T p.M205I | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- RUBCN | c.1792G>A p.D598N | Missense Mutation (SNP) | VAF 339/575 reads (59%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- RYR2 | c.14591-1G>T p.X4864_splice | Splice Site (SNP) | VAF 41/69 reads (59%) | called by muse, mutect2, varscan2
- SLC41A1 | c.990C>T p.S330= | Splice Region (SNP) | VAF 72/368 reads (20%) | called by muse, mutect2, varscan2
- SLC4A10 | c.1933T>C p.F645L (on ENST00000446997 / NM_001354461.2; = p.F615L on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/192 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SLC6A18 | c.200A>T p.E67V | Missense Mutation (SNP) | VAF 20/388 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- SLFN14 | c.2164C>G p.Q722E | Missense Mutation (SNP) | VAF 85/277 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- SPTA1 | c.4873G>T p.E1625* | Nonsense Mutation (SNP) | VAF 158/804 reads (20%) | called by muse, mutect2, varscan2
- SPTBN5 | c.1609A>T p.S537C | Missense Mutation (SNP) | VAF 54/89 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- SRRM1 | c.1880C>T p.P627L | Missense Mutation (SNP) | VAF 91/287 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- STOX1 | c.411G>C p.Q137H | Missense Mutation (SNP) | VAF 80/238 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- SYT13 | c.202_209del p.T68Cfs*49 | Frame Shift Del (DEL) | VAF 40/154 reads (26%) | called by mutect2, pindel
- TANK | c.404+2T>C p.X135_splice | Splice Site (SNP) | VAF 46/198 reads (23%) | called by muse, mutect2, varscan2
- TIMM10 | c.10C>T p.L4F | Missense Mutation (SNP) | VAF 63/194 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- TNFRSF9 | c.535A>T p.R179* | Nonsense Mutation (SNP) | VAF 25/69 reads (36%) | called by muse, mutect2, varscan2
- TRIO | c.8848C>A p.H2950N | Missense Mutation (SNP) | VAF 78/468 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TYK2 | c.3315del p.T1106Rfs*7 | Frame Shift Del (DEL) | VAF 18/50 reads (36%) | called by pindel, varscan2
- UNC80 | c.4867G>C p.E1623Q | Missense Mutation (SNP) | VAF 61/125 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- USP26 | c.266C>T p.T89I | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- ZNF684 | c.705A>T p.R235S | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ABCA5 | c.1893G>A p.G631= | Silent (SNP) | VAF 66/179 reads (37%) | called by muse, mutect2, varscan2
- ARNTL | c.210A>C p.I70= | Silent (SNP) | VAF 46/72 reads (64%) | called by muse, mutect2, varscan2
- ASXL2 | c.24G>A p.K8= | Silent (SNP) | VAF 63/197 reads (32%) | catalogued as rs1343028890; called by muse, mutect2, varscan2
- CAPN14 | c.1035C>A p.A345= | Silent (SNP) | VAF 73/206 reads (35%) | catalogued as COSV101294553; called by muse, mutect2, varscan2
- CEBPZ | c.3042A>G p.R1014= | Silent (SNP) | VAF 39/125 reads (31%) | catalogued as rs756236129; called by muse, mutect2, varscan2
- CHD6 | c.7839C>T p.L2613= | Silent (SNP) | VAF 91/130 reads (70%) | catalogued as rs948256098; called by muse, mutect2, varscan2
- DSCAM | c.4194T>C p.S1398= | Silent (SNP) | VAF 106/264 reads (40%) | catalogued as COSV68035691, COSV68039722; called by muse, mutect2, varscan2
- FMN2 | c.474G>T p.P158= | Silent (SNP) | VAF 52/197 reads (26%) | catalogued as rs1198977248, COSV60417397; called by muse, varscan2
- GPR107 | c.18C>T p.P6= | Silent (SNP) | VAF 35/121 reads (29%) | catalogued as rs760429542; called by muse, mutect2, varscan2
- KAT6B | c.5325C>T p.F1775= | Silent (SNP) | VAF 41/134 reads (31%) | catalogued as COSV104380587; called by muse, mutect2, varscan2
- KRT26 | c.564C>T p.A188= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as rs759949567, COSV59413431; called by muse, mutect2, varscan2
- LGR6 | c.630C>A p.T210= (on ENST00000367278 / NM_001017403.1; = p.T158= on NM_021636.3) | Silent (SNP) | VAF 20/97 reads (21%) | called by muse, mutect2
- MAP6 | c.1473G>A p.G491= | Silent (SNP) | VAF 74/201 reads (37%) | called by muse, mutect2, varscan2
- MED12L | c.1653T>C p.D551= | Silent (SNP) | VAF 127/190 reads (67%) | called by muse, mutect2, varscan2
- MED12L | c.4851T>C p.S1617= | Silent (SNP) | VAF 250/406 reads (62%) | called by muse, varscan2
- NHLH2 | c.201G>A p.E67= | Silent (SNP) | VAF 84/213 reads (39%) | catalogued as rs1171289145; called by muse, mutect2, varscan2
- NQO1 | c.529C>T p.L177= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs1363535492, COSV57732242; called by muse, varscan2
- OR4K1 | c.615G>A p.L205= | Silent (SNP) | VAF 39/151 reads (26%) | catalogued as COSV53459075; called by muse, mutect2, varscan2
- OR6C68 | c.165A>G p.T55= | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as rs749817023; called by muse, mutect2, varscan2
- PGAP6 | c.219C>T p.P73= | Silent (SNP) | VAF 69/117 reads (59%) | catalogued as rs371665043; called by muse, mutect2, varscan2
- PML | c.2247C>A p.A749= | Silent (SNP) | VAF 21/95 reads (22%) | called by muse, mutect2, varscan2
- PRKG1 | c.1779A>G p.E593= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as rs1478526424; ClinVar: likely benign; called by muse, mutect2, varscan2
- RHO | c.984G>C p.L328= | Silent (SNP) | VAF 18/176 reads (10%) | catalogued as rs1422707451, COSV56213728; called by mutect2, varscan2
- RYR3 | c.2316C>T p.D772= | Silent (SNP) | VAF 23/38 reads (61%) | catalogued as rs770405615, COSV66792194; called by muse, mutect2, varscan2
- SHISA6 | c.1038C>A p.I346= (on ENST00000409168 / NM_001173461.1; = p.I397= on NM_207386.4) | Silent (SNP) | VAF 23/42 reads (55%) | catalogued as COSV101305754; called by muse, mutect2, varscan2
- SPATA31D1 | c.468G>A p.V156= | Silent (SNP) | VAF 111/269 reads (41%) | catalogued as rs1281620925; called by muse, mutect2, varscan2
- TMEM130 | c.786C>A p.T262= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as rs374694999; called by muse, mutect2, varscan2
- TNFRSF9 | c.534G>C p.A178= | Silent (SNP) | VAF 26/70 reads (37%) | catalogued as rs28360480, COSV66349966; called by muse, mutect2, varscan2
- TONSL | c.3207C>T p.H1069= | Silent (SNP) | VAF 24/95 reads (25%) | catalogued as rs1554879368; called by muse, mutect2, varscan2
- TULP4 | c.81C>G p.P27= | Silent (SNP) | VAF 93/156 reads (60%) | catalogued as rs751287104; called by muse, mutect2, varscan2
- UNC5A | c.774C>T p.C258= | Silent (SNP) | VAF 49/198 reads (25%) | called by muse, mutect2, varscan2
- ZHX3 | c.2406T>A p.G802= | Silent (SNP) | VAF 109/148 reads (74%) | called by muse, mutect2, varscan2
- ZNF394 | c.438C>T p.L146= | Silent (SNP) | VAF 9/27 reads (33%) | called by muse, varscan2
- C4orf50 | c.-902G>T | 5'UTR (SNP) | VAF 55/209 reads (26%) | called by muse, mutect2, varscan2
- CATSPER4 | c.1199+22G>A | Intron (SNP) | VAF 55/164 reads (34%) | called by muse, mutect2, varscan2
- COL21A1 | c.2408-55_2408-52del | Intron (DEL) | VAF 41/154 reads (27%) | called by mutect2, pindel, varscan2
- CSNK1A1 | c.456+2436G>C | Intron (SNP) | VAF 49/234 reads (21%) | catalogued as COSV99939782; called by muse, mutect2, varscan2
- CTBP1 | c.*9G>A | 3'UTR (SNP) | VAF 16/42 reads (38%) | called by muse, mutect2
- DOCK8 | c.3390+11A>T | Intron (SNP) | VAF 57/183 reads (31%) | called by muse, mutect2, varscan2
- EIF2B4 | c.1192-9G>C | Intron (SNP) | VAF 19/277 reads (7%) | called by muse, mutect2
- FBXL7 | c.-29del | 5'UTR (DEL) | VAF 72/562 reads (13%) | called by mutect2, pindel, varscan2
- GALNS | c.121-35G>C | Intron (SNP) | VAF 14/37 reads (38%) | called by muse, mutect2, varscan2
- GANC | c.201+2490T>C | Intron (SNP) | VAF 75/127 reads (59%) | called by muse, mutect2, varscan2
- GPC1 | c.167-5988C>T | Intron (SNP) | VAF 42/107 reads (39%) | catalogued as rs1370703850; called by muse, mutect2, varscan2
- GUSBP10 | n.140C>T | RNA (SNP) | VAF 50/162 reads (31%) | catalogued as rs567835031; called by muse, mutect2, varscan2
- HECTD1 | c.5673+27C>A | Intron (SNP) | VAF 23/57 reads (40%) | called by muse, mutect2, varscan2
- LAMC3 | c.-9C>T | 5'UTR (SNP) | VAF 5/8 reads (63%) | catalogued as rs1253412902; called by muse, varscan2
- LETM2 | c.645+2844C>T | Intron (SNP) | VAF 60/218 reads (28%) | called by muse, varscan2
- LETM2 | c.*4A>T | 3'UTR (SNP) | VAF 52/226 reads (23%) | called by mutect2, varscan2
- LHX1 | chr17:36937144 G>T | 5'Flank (SNP) | VAF 37/97 reads (38%) | called by muse, mutect2, varscan2
- MED14 | c.-67del | 5'UTR (DEL) | VAF 24/45 reads (53%) | called by mutect2, pindel, varscan2
- MIR541 | n.35C>A | RNA (SNP) | VAF 43/114 reads (38%) | called by muse, mutect2, varscan2
- NDEL1 | c.-31C>T | 5'UTR (SNP) | VAF 10/54 reads (19%) | catalogued as rs1006637786; called by muse, mutect2, varscan2
- NEDD4L | c.2753-44C>G | Intron (SNP) | VAF 32/134 reads (24%) | called by muse, mutect2, varscan2
- OR2U1P | n.768G>A | RNA (SNP) | VAF 45/165 reads (27%) | called by muse, mutect2, varscan2
- OXT | c.*15G>A | 3'UTR (SNP) | VAF 44/135 reads (33%) | catalogued as rs17339677, COSV99459169; called by muse, mutect2, varscan2
- PRPF3 | c.277-22del | Intron (DEL) | VAF 52/291 reads (18%) | called by mutect2, pindel, varscan2
- PVALEF | c.-95G>T | 5'UTR (SNP) | VAF 9/38 reads (24%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159154 G>T | 5'Flank (SNP) | VAF 36/106 reads (34%) | called by muse, varscan2
- SCMH1 | chr1:41161411 C>G | 5'Flank (SNP) | VAF 35/142 reads (25%) | called by muse, mutect2, varscan2
- SLC7A10 | c.788+15C>G | Intron (SNP) | VAF 25/188 reads (13%) | catalogued as rs1200086320; called by muse, mutect2, varscan2
- SQLE | c.-897G>A | 5'UTR (SNP) | VAF 16/30 reads (53%) | called by muse, mutect2
- STAG2 | c.-26G>C | 5'UTR (SNP) | VAF 44/57 reads (77%) | called by muse, mutect2, varscan2
- STAT1 | c.1873+48G>A | Intron (SNP) | VAF 16/180 reads (9%) | called by muse, mutect2
- TBC1D31 | c.77+538G>A | Intron (SNP) | VAF 255/433 reads (59%) | called by muse, mutect2, varscan2
- TMEM92 | c.*37C>T | 3'UTR (SNP) | VAF 60/162 reads (37%) | called by muse, mutect2, varscan2
- TPM2 | chr9:35682786 G>A | 3'Flank (SNP) | VAF 70/180 reads (39%) | called by muse, mutect2, varscan2
